TARGET case TARGET-20-PASRRG — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/41059992-2356-4045-aceb-12dbdf3cf29e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 17 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 17.2 years (6,277 days); Year of diagnosis: 2009; Days to last follow up: 4,134 days (11.3 years).
   Treatment given: Protocol identifier: AAML0631.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (2 entries)
- Days to follow up: 740 days (2.0 years); Days to first event: 740 days (2.0 years); First event: Relapse.
- Days to follow up: 4,134 days (11.3 years); Year of follow up: 2020.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 9.3 ×10³/µL; Blast Count 51%; Bone Marrow blast count 90%.

Biospecimens (1 sample)
- Sample TARGET-20-PASRRG-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- Overall Survival Time in Days: 4134
- WBC at Diagnosis: 9.3
- Bone marrow leukemic blast percentage (%): 90
- Peripheral blasts (%): 51
- FAB Category: M3
- Cytogenetic Complexity: 1
- Primary Cytogenetic Code: PML-RARA
- ISCN: 46,XY,t(15;17)(q22;q21)[20]
- SCT in 1st CR: No
- Bone Marrow Site of Relapse/Induction Failure: Yes
- CNS Site of Relapse/Induction Failure: Yes
- Chloroma Site of Relapse/Induction Failure: No
- Cytogenetic Site of Relapse/Induction Failure: No
- Other Site of Relapse/Induction Failure: No
